Somatic mutation profile of tumor specimen TCGA-85-8481-01A (aliquot TCGA-85-8481-01A-11D-2323-08) from TCGA case TCGA-85-8481, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.6 years (25,782 days).
Specimen TCGA-85-8481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f056640-44b9-4b20-be34-3cde44885cc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8481-10A (Blood Derived Normal), aliquot TCGA-85-8481-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/511aefef-1091-49af-9be1-0366a3c4b611

The open-access MAF lists 342 somatic variants for this specimen: 252 protein-altering or splice-affecting, 79 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 79, Nonsense Mutation 17, Splice Site 9, Frame Shift Del 9, Frame Shift Ins 4, RNA 4, Intron 4, 3'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCC | c.1628C>A p.S543* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs867319477, COSV56660764; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3395C>A p.P1132H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99793044, COSV99793125; called by muse, mutect2
- ABCB4 | c.360C>G p.Y120* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99711261; called by muse, mutect2
- AC092143.1 | c.1726G>T p.V576L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100206071; called by muse, mutect2, varscan2
- ACKR1 | c.597C>A p.Y199* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1416541424, COSV100929662; called by muse, mutect2
- ACRV1 | c.5A>T p.N2I | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV100223624; called by muse, mutect2, varscan2
- ADAMTS2 | c.2053G>T p.A685S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV52387833; called by muse, mutect2, varscan2
- ADAMTS5 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99538320; called by muse, mutect2
- ADRA1A | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372130; called by muse, mutect2, varscan2
- AKAP1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV58469228; called by muse, mutect2, varscan2
- AKAP3 | c.2371T>C p.Y791H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99962610; called by muse, mutect2, varscan2
- AKAP9 | c.2899A>G p.K967E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV100663079; called by muse, mutect2, varscan2
- ALPK1 | c.3324A>G p.I1108M | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99455148; called by muse, mutect2, varscan2
- APBB3 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100021493; called by muse, mutect2, varscan2
- APOB | c.6146C>G p.P2049R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99267985; called by muse, mutect2
- APOB | c.6145C>G p.P2049A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99264921, COSV99267989; called by muse, mutect2
- APOB | c.3051C>A p.S1017R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV51921739, COSV99267990; called by muse, mutect2, varscan2
- ARFGEF2 | c.4454+2T>A p.X1485_splice | Splice Site (SNP) | VAF 45/171 reads (26%) | catalogued as COSV100904471; called by muse, mutect2, varscan2
- ARFGEF3 | c.6307A>T p.S2103C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV99294665; called by muse, mutect2
- ARHGAP15 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99713493; called by muse, mutect2
- ARHGAP15 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99713494; called by muse, mutect2, varscan2
- ARHGAP20 | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99505317; called by muse, mutect2, varscan2
- ARHGAP35 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68336836; called by muse, mutect2
- ARMC6 | c.1459G>C p.E487Q (on ENST00000392336; = p.E462Q on NM_033415.4) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99523178; called by muse, mutect2, varscan2
- ARSJ | c.150A>T p.L50F | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.091); catalogued as COSV100193132; called by muse, mutect2
- ASAP3 | c.1343-1G>A p.X448_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100369665; called by muse, mutect2, varscan2
- ASXL1 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041068, COSV60102834; called by muse, varscan2
- ATM | c.7950C>G p.D2650E | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99591852; called by muse, mutect2
- ATP1A4 | c.2252C>A p.A751E | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100927642; called by muse, mutect2, varscan2
- B3GAT2 | c.547T>C p.F183L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs781459405, COSV100017417; called by muse, mutect2, varscan2
- B4GALNT3 | c.1927C>G p.L643V | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV56756003, COSV99843595; called by muse, mutect2
- BRF2 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV99605116; called by muse, mutect2
- BRINP3 | c.2086del p.Q696Rfs*9 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as COSV100819645, COSV66529458; called by mutect2, pindel, varscan2
- CACNB2 | c.885G>T p.E295D (on ENST00000324631 / NM_201596.3; = p.E240D on NM_000724.4) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56624069, COSV99996319; called by muse, mutect2
- CALB2 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100226421; called by muse, mutect2, varscan2
- CALCR | c.1096C>A p.P366T (on ENST00000649521 / NM_001164737.2; = p.P350T on NM_001742.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100810859; called by muse, mutect2, varscan2
- CALHM5 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100635667, COSV62067327; called by muse, mutect2, varscan2
- CASP5 | c.548A>C p.Y183S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52829664; called by muse, mutect2, varscan2
- CCDC138 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs777265536, COSV99719422; called by muse, mutect2, varscan2
- CCDC150 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV99777369; called by muse, mutect2
- CCDC39 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs748151034, COSV99870604; called by muse, mutect2, varscan2
- CDH12 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as COSV101203308; called by muse, mutect2, varscan2
- CDK12 | c.2665A>T p.S889C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101420532; called by muse, mutect2, varscan2
- CELSR3 | c.9626G>A p.S3209N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99374916; called by muse, mutect2, varscan2
- CEP162 | c.4018A>G p.T1340A | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100003377, COSV57618309; called by mutect2, varscan2
- CFAP61 | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844917, COSV99846632; called by mutect2, varscan2
- CLPTM1 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV100493952; called by muse, mutect2, varscan2
- CNTNAP2 | c.1935G>T p.Q645H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV100672495; called by muse, mutect2, varscan2
- COL22A1 | c.2519G>T p.G840V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280734; called by muse, mutect2, varscan2
- COL22A1 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV100280736; called by muse, mutect2
- COL25A1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101211635; called by muse, mutect2, varscan2
- CPNE3 | c.312+1G>A p.X104_splice | Splice Site (SNP) | VAF 33/136 reads (24%) | catalogued as COSV99548088; called by muse, mutect2, varscan2
- CPNE6 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV53745937; called by muse, mutect2, varscan2
- CPQ | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55145505, COSV99614640; called by muse, mutect2
- CROT | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.428); catalogued as COSV100519683; called by muse, mutect2, varscan2
- CSRNP3 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV100086317; called by muse, mutect2, varscan2
- CTH | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100697155; called by muse, mutect2, varscan2
- CTSV | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV99414443; called by muse, mutect2
- CYP4F2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV99171142; called by muse, mutect2, varscan2
- D2HGDH | c.831G>T p.R277S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV100344928; called by muse, mutect2, varscan2
- DCLK1 | c.1327G>T p.V443L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV99713019; called by muse, mutect2, varscan2
- DCN | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV50007247, COSV99272775; called by muse, mutect2, varscan2
- DLD | c.1115T>A p.I372N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99227509; called by muse, mutect2, varscan2
- DLG2 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54669126, COSV99719587; called by muse, mutect2, varscan2
- DLG2 | c.310-1G>T p.X104_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54621035, COSV99719590; called by muse, mutect2, varscan2
- DNAAF1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV100533826; called by muse, mutect2, varscan2
- DNAH5 | c.12082G>A p.V4028I | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV99454070; called by muse, mutect2, varscan2
- DOCK6 | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as CM155663, COSV53912788, COSV99626650; called by mutect2, varscan2
- DPYSL5 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99982792; called by muse, mutect2
- ENPP3 | c.2399G>T p.W800L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as COSV100718059; called by muse, mutect2, varscan2
- ERICH3 | c.3355C>A p.P1119T | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV58598779; called by muse, mutect2, varscan2
- ERICH3 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 60/381 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV100445714; called by muse, mutect2, varscan2
- FAM174A | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as COSV57062006, COSV57063897; called by muse, mutect2, varscan2
- FCRL2 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.292); catalogued as COSV100830005; called by muse, mutect2
- FGD3 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100490889; called by muse, mutect2, varscan2
- FMN2 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100147077, COSV60431203; called by muse, mutect2, varscan2
- FMR1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.155); catalogued as COSV99503782; called by muse, mutect2
- FOXB2 | c.617C>G p.S206W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV100942390; called by muse, mutect2, varscan2
- FOXD4L5 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as COSV101073270, COSV101073300; called by muse, mutect2, varscan2
- FRY | c.6701G>C p.G2234A | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100969895; called by muse, mutect2, varscan2
- FSIP2 | c.18266A>G p.Y6089C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100556476; called by muse, mutect2, varscan2
- GABRB1 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99783440; called by muse, mutect2
- GAD2 | c.1126A>T p.K376* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV99394024; called by muse, mutect2
- GALR1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100231782, COSV100232093; called by muse, mutect2
- GAPDHS | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99722906; called by muse, mutect2, varscan2
- GAPDHS | c.933T>A p.D311E | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV99722492; called by muse, mutect2, varscan2
- GFAP | c.1291G>A p.E431K (on ENST00000253408 / NM_001363846.2; = p.G431S on NM_001131019.3) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs370385098; called by muse, mutect2, varscan2
- GOLIM4 | c.2081C>A p.A694D | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100463459; called by muse, mutect2, varscan2
- GPC5 | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100994745, COSV100995948; called by muse, mutect2
- GPIHBP1 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as COSV100427401; called by muse, mutect2
- GPR108 | c.1489C>T p.Q497* (on ENST00000264080 / NM_001080452.1; = p.Q255* on NM_020171.2) | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV99901539; called by muse, mutect2, varscan2
- GPR156 | c.592A>G p.S198G | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1313837532, COSV100251712; called by muse, mutect2
- GRID1 | c.2851C>G p.L951V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV100026441; called by muse, mutect2
- GRIK3 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100902314; called by muse, mutect2
- GSTA5 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV99489729; called by muse, mutect2, varscan2
- GTF3C1 | c.1126+2T>G p.X376_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | catalogued as COSV100649696; called by muse, mutect2, varscan2
- HCLS1 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100101150; called by muse, mutect2, varscan2
- HHIPL1 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100415398; called by muse, mutect2, varscan2
- HLA-DRA | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV66623111; called by muse, mutect2, varscan2
- HMCN1 | c.4223A>T p.Q1408L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV99635483; called by muse, mutect2, varscan2
- HMCN1 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99635484; called by muse, mutect2, varscan2
- HOXD1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs775166165, COSV100514255; called by muse, mutect2, varscan2
- HOXD10 | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99982348; called by muse, mutect2
- IBTK | c.583A>C p.K195Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as COSV100091479; called by muse, mutect2, varscan2
- IL12B | c.158del p.P53Lfs*17 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as COSV51454870; called by mutect2, pindel, varscan2
- INTS4 | c.2050C>G p.P684A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV100490127; called by muse, mutect2, varscan2
- ITPRID1 | c.2609T>C p.M870T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1001765695, COSV100087486; called by muse, mutect2
- JAG2 | c.1025G>T p.R342M | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as COSV100078816; called by muse, mutect2, varscan2
- JUP | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs781828085, COSV60279031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB1 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870590; called by muse, mutect2, varscan2
- KCNH5 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528105, COSV59774196; called by muse, mutect2, varscan2
- KCNH7 | c.18del p.H7Mfs*45 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | catalogued as COSV59794559; called by mutect2, pindel
- KCNK13 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV56412695; called by muse, mutect2, varscan2
- KIAA0319 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100985802; called by muse, mutect2, varscan2
- KIAA1841 | c.901T>C p.C301R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs1188986476, COSV99694224; called by muse, mutect2
- LPO | c.1344C>A p.Y448* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99229388; called by muse, mutect2, varscan2
- LRP1B | c.3371A>T p.D1124V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101260847; called by muse, mutect2, varscan2
- LRP1B | c.1289A>T p.N430I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101260848; called by muse, mutect2, varscan2
- LRP2 | c.12212C>T p.S4071F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99790222; called by muse, mutect2, varscan2
- LRRC7 | c.3208C>A p.Q1070K (on ENST00000651989 / NM_001370785.2; = p.Q1037K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99229688; called by muse, mutect2, varscan2
- LURAP1L | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100070913, COSV100070963; called by muse, mutect2, varscan2
- MAD1L1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs61751745, COSV56251681, COSV99765150; called by muse, mutect2, varscan2
- METAP1D | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100250129; called by muse, mutect2, varscan2
- METTL4 | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1296777396, COSV100170741; called by muse, mutect2, varscan2
- MPHOSPH10 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1181028243, COSV99731286; called by muse, mutect2, varscan2
- MROH5 | c.2220G>T p.W740C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV101436127; called by muse, mutect2, varscan2
- MRPS5 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs186030997, COSV99721050; called by muse, mutect2, varscan2
- MTDH | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV100292777; called by muse, mutect2, varscan2
- MUC16 | c.23425C>G p.L7809V | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.006); catalogued as COSV101201589, COSV67464785; called by muse, mutect2, varscan2
- MUC4 | c.14141G>T p.G4714V (on ENST00000463781 / NM_018406.7; = p.G478V on NM_004532.6) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100206429; called by muse, mutect2, varscan2
- MYPN | c.3701A>C p.Q1234P | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100590615; called by muse, mutect2, varscan2
- N4BP2 | c.2740A>T p.T914S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV99789266; called by muse, mutect2, varscan2
- NAV2 | c.2377A>T p.S793C (on ENST00000396087 / NM_001244963.2; = p.S770C on NM_145117.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100586984; called by muse, mutect2, varscan2
- NAV2 | c.2378G>T p.S793I (on ENST00000396087 / NM_001244963.2; = p.S770I on NM_145117.5) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100586988; called by muse, mutect2, varscan2
- NEB | c.11378T>C p.I3793T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as COSV99427873; called by muse, mutect2, varscan2
- NLRP4 | c.1866C>A p.Y622* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100017151; called by muse, mutect2, varscan2
- NLRP4 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs780315154, COSV56708392; called by muse, mutect2
- NR1D1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as COSV99225787; called by muse, mutect2
- NRIP1 | c.3242G>T p.S1081I | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV100013101; called by muse, mutect2
- NT5E | c.1529T>A p.M510K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100004340; called by muse, mutect2, varscan2
- NTNG1 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99639400; called by muse, mutect2, varscan2
- NUMA1 | c.3479G>A p.R1160Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762820306, COSV100706596; called by muse, mutect2, varscan2
- NXPH4 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61073631; called by muse, mutect2, varscan2
- NYNRIN | c.648_649insT p.D217* | Frame Shift Ins (INS) | VAF 17/109 reads (16%) | catalogued as COSV101230700; called by mutect2, pindel, varscan2
- OGT | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV101035623; called by muse, mutect2, varscan2
- OLFM1 | c.375G>A p.M125I (on ENST00000371793 / NM_001282611.2; = p.M107I on NM_006334.4) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV99424283; called by muse, mutect2
- OLFM1 | c.552G>T p.E184D (on ENST00000371793 / NM_001282611.2; = p.E166D on NM_014279.5) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV99424285; called by muse, mutect2, varscan2
- OPLAH | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV101470936; called by muse, mutect2, varscan2
- OPRD1 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52381623, COSV99330529; called by muse, mutect2, varscan2
- OR1L6 | c.568C>A p.H190N (on ENST00000373684; = p.H154N on NM_001004453.2) | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.815); catalogued as COSV100490993; called by muse, mutect2
- OR4C13 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.012); catalogued as COSV101634215, COSV101634240; called by muse, mutect2, varscan2
- OR4D2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV101613866; called by muse, mutect2, varscan2
- OR4E2 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100330159; called by muse, mutect2, varscan2
- OR4K2 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100064752; called by muse, varscan2
- OR51E2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV101211403; called by muse, mutect2, varscan2
- OR5W2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100747752; called by muse, mutect2, varscan2
- OR6K3 | c.361C>A p.H121N (on ENST00000368146; = p.H105N on NM_001005327.2) | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100933889; called by muse, mutect2, varscan2
- PAPOLA | c.1189A>G p.K397E | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99354625; called by muse, varscan2
- PCDH15 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946296710, COSV100226003, COSV57265845, COSV57331271; called by muse, mutect2
- PCDHB10 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as COSV99505017; called by muse, mutect2, varscan2
- PCDHB7 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50810559; called by muse, mutect2, varscan2
- PDE3B | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 151/215 reads (70%) | catalogued as COSV99963245; called by muse, mutect2, varscan2
- PDE8B | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV99367569; called by muse, mutect2, varscan2
- PDIK1L | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as COSV65323067; called by muse, mutect2, varscan2
- PHLDB1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV100616773; called by muse, mutect2, varscan2
- PIK3C3 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100011587; called by muse, mutect2, varscan2
- PIK3R1 | c.1664A>C p.E555A (on ENST00000521381 / NM_181523.3; = p.E285A on NM_181504.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99153152; called by muse, mutect2, varscan2
- PKHD1 | c.2452C>A p.Q818K | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV100584531; called by muse, mutect2, varscan2
- PLCH2 | c.2078A>G p.Y693C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99617103; called by muse, mutect2, varscan2
- PLXDC1 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100195828; called by muse, mutect2
- PLXNA4 | c.4286G>T p.R1429M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100327004; called by muse, mutect2, varscan2
- PLXNA4 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327008; called by muse, mutect2, varscan2
- POLE | c.5992A>G p.M1998V | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57678030, COSV57678040; called by muse, mutect2, varscan2
- PRLR | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV99184770; called by muse, mutect2, varscan2
- PRPS1 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV100978922; called by muse, mutect2, varscan2
- PSG9 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 37/396 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755539714, COSV52485807; called by muse, mutect2
- PSME2 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.802); catalogued as COSV53756454, COSV99395721; called by muse, mutect2, varscan2
- PTPRO | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV99841717; called by muse, mutect2, varscan2
- PTPRT | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV62036813; called by muse, mutect2, varscan2
- RBM43 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100508654; called by muse, mutect2
- RELN | c.10138A>C p.K3380Q | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.968); catalogued as COSV100634914; called by muse, mutect2, varscan2
- ROPN1L | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99928775; called by muse, mutect2, varscan2
- RPL37A | c.181A>G p.M61V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs767492787, COSV100677114; called by muse, mutect2, varscan2
- RYR1 | c.7229C>A p.P2410Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV100616972; called by muse, mutect2, varscan2
- SAMD3 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100148420; called by muse, varscan2
- SAMD8 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101014185; called by muse, mutect2, varscan2
- SATB2 | c.1719G>T p.Q573H | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53479151, COSV99612637; called by muse, mutect2
- SCN2A | c.3092G>T p.R1031M | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV99333436; called by muse, mutect2, varscan2
- SCN2A | c.3093G>T p.R1031S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.217); catalogued as COSV99333440; called by muse, mutect2, varscan2
- SCYL2 | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as COSV100675310; called by muse, mutect2, varscan2
- SDC3 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767402418, COSV59579449; called by muse, mutect2, varscan2
- SEC23IP | c.19A>T p.N7Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100957091; called by muse, mutect2, varscan2
- SELP | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV55251853; called by muse, mutect2, varscan2
- SENP7 | c.1376A>T p.K459M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100053870; called by muse, mutect2, varscan2
- SF3B4 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV99641423; called by muse, mutect2, varscan2
- SH3KBP1 | c.152A>T p.N51I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV101115191; called by muse, mutect2, varscan2
- SIGLECL1 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100324009; called by muse, mutect2, varscan2
- SLC12A6 | c.3416G>T p.R1139L (on ENST00000354181 / NM_001365088.1; = p.R1088L on NM_005135.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99273374; called by muse, mutect2, varscan2
- SLC4A3 | c.2386G>T p.V796F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99813217; called by muse, mutect2, varscan2
- SLC4A5 | c.1910A>C p.E637A | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698007; called by muse, mutect2, varscan2
- SLC4A5 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100698009; called by muse, mutect2, varscan2
- SLCO6A1 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as COSV101134952; called by muse, mutect2, varscan2
- SMTNL1 | c.701C>A p.S234Y (on ENST00000399154; = p.S271Y on NM_001105565.2) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101216551; called by muse, mutect2
- SMYD1 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101352514; called by muse, mutect2, varscan2
- SOHLH2 | c.69A>C p.L23F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100499528, COSV58523638; called by muse, mutect2, varscan2
- SPEF2 | c.2038-1G>T p.X680_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100608862; called by muse, mutect2, varscan2
- ST3GAL2 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen benign (0.054); catalogued as COSV100735768; called by muse, mutect2
- ST3GAL2 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen benign (0.44); catalogued as COSV100735769; called by muse, mutect2
- STON1 | c.559T>C p.W187R | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562279; called by muse, mutect2, varscan2
- STRBP | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100724363; called by muse, mutect2
- TAB3 | c.1769G>T p.C590F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916821; called by muse, mutect2, varscan2
- TATDN1 | c.23-2A>T p.X8_splice | Splice Site (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99413707; called by muse, mutect2, varscan2
- TCF12 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV99978917; called by muse, varscan2
- TFRC | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100786600; called by muse, mutect2, varscan2
- TGIF2LX | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99383532; called by muse, mutect2, varscan2
- THEMIS | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs138041742, COSV64070371; called by muse, mutect2, varscan2
- THSD7B | c.2315C>A p.A772E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1486431565, COSV99757959; called by muse, mutect2, varscan2
- TLE6 | c.990A>G p.I330M (on ENST00000246112 / NM_001143986.2; = p.I207M on NM_024760.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV99858507; called by muse, mutect2, varscan2
- TMEM132D | c.2222A>G p.K741R | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.157); catalogued as COSV101243086; called by muse, mutect2, varscan2
- TMEM132E | c.1499A>G p.Y500C (on ENST00000321639; = p.Y590C on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100396780; called by muse, mutect2
- TRIP10 | c.1439del p.G480Efs*4 (on ENST00000313244 / NM_001288962.2; = p.G424Efs*4 on NM_004240.4) | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as COSV55584635; called by mutect2, pindel, varscan2
- TRPA1 | c.1920C>A p.F640L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100085159; called by muse, mutect2
- TRPM6 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765240878, COSV62512065; called by muse, mutect2, varscan2
- TTN | c.89987C>A p.A29996D (on ENST00000591111; = p.A22572D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | PolyPhen probably damaging (0.976); catalogued as COSV100629395; called by muse, mutect2, varscan2
- TTN | c.23324G>C p.G7775A (on ENST00000591111; = p.G6848A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | PolyPhen possibly damaging (0.475); catalogued as COSV100629398, COSV60291061; called by muse, mutect2
- TUBB8 | c.1018T>A p.Y340N | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100226199; called by muse, mutect2, varscan2
- UEVLD | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100293387; called by muse, mutect2, varscan2
- UNC13C | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99520998; called by muse, mutect2, varscan2
- USH2A | c.9385G>T p.D3129Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV56407602, COSV56451594; called by muse, mutect2, varscan2
- UST | c.681+2T>C p.X227_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100820149; called by muse, mutect2, varscan2
- UTRN | c.6156C>G p.S2052R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs114336646, COSV100840629; called by muse, mutect2, varscan2
- ZNF32 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100986519; called by muse, mutect2
- ZNF485 | c.1283A>G p.H428R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100700286; called by muse, mutect2, varscan2
- ZNF496 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54181719, COSV99666146; called by muse, mutect2, varscan2
- ZNF516 | c.3040G>T p.A1014S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV101487367; called by muse, mutect2, varscan2
- ZNF701 | c.280G>T p.A94S (on ENST00000301093; = p.A28S on NM_018260.3) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV99990993; called by muse, mutect2, varscan2
- ZNF770 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as COSV100696053; called by muse, mutect2
- ZNF780B | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99666113; called by muse, mutect2, varscan2
- ZNF80 | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100352011, COSV100352058, COSV57360062; called by muse, mutect2, varscan2
- AP5Z1 | c.26dup p.L9Ffs*22 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel, varscan2
- B4GALT4 | c.764del p.G255Dfs*18 | Frame Shift Del (DEL) | VAF 29/154 reads (19%) | called by mutect2, pindel, varscan2
- CES1 | c.1315+1G>T p.X439_splice (on ENST00000361503 / NM_001025194.2; = p.X438_splice on NM_001266.5) | Splice Site (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- GFPT1 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- IRF6 | c.1275_1281del p.P426Sfs*9 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- PCDH11Y | c.1976del p.P659Qfs*17 (on ENST00000400457 / NM_032973.2; = p.P648Qfs*17 on NM_032971.3) | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCSK2 | c.227dup p.A77Gfs*29 | Frame Shift Ins (INS) | VAF 26/177 reads (15%) | called by mutect2, pindel, varscan2
- PLPP7 | c.89del p.K30Rfs*44 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- RASA1 | c.806_810del p.L269Pfs*11 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- UGT1A5 | c.683_684dup p.A229Lfs*35 | Frame Shift Ins (INS) | VAF 42/262 reads (16%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABCA7 | c.2943G>C p.L981= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99566647; called by muse, mutect2, varscan2
- ABCB1 | c.1695C>T p.S565= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs59697741, COSV99714337; called by muse, mutect2, varscan2
- ADGRB3 | c.3622C>A p.R1208= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV53239154, COSV99486817; called by muse, mutect2, varscan2
- ADGRE2 | c.1938C>A p.L646= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100216498; called by muse, mutect2, varscan2
- ANKRD30A | c.3747C>A p.L1249= (on ENST00000611781; = p.L1193= on NM_052997.2) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100654429; called by muse, varscan2
- ATM | c.3954C>G p.V1318= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV53747644, COSV99591846; called by muse, mutect2, varscan2
- ATP13A4 | c.3180A>G p.K1060= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV100710732; called by muse, mutect2, varscan2
- AWAT2 | c.459T>C p.Y153= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99339775; called by muse, mutect2, varscan2
- BANK1 | c.1020C>T p.F340= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100536844; called by muse, mutect2
- CBR1 | c.564C>G p.G188= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99289608; called by muse, mutect2, varscan2
- CDH10 | c.339C>A p.A113= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100053091; called by muse, mutect2, varscan2
- CEACAM5 | c.1188G>A p.Q396= | Silent (SNP) | VAF 19/248 reads (8%) | catalogued as COSV55756458; called by muse, mutect2
- CELSR3 | c.5556G>T p.R1852= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV99374920; called by muse, mutect2, varscan2
- CHRM3 | c.1605C>A p.I535= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV99079567, COSV99699451; called by muse, mutect2, varscan2
- CLPB | c.180G>T p.P60= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99578673; called by muse, mutect2, varscan2
- COBL | c.2394G>T p.T798= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV104371538, COSV99474136; called by muse, mutect2, varscan2
- CPLX4 | c.321G>T p.R107= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100231549; called by muse, mutect2, varscan2
- CR2 | c.1185C>A p.A395= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100889707; called by muse, mutect2, varscan2
- CROCC | c.5254C>T p.L1752= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100978400; called by muse, mutect2
- CYLC1 | c.1638A>G p.E546= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100255481; called by muse, mutect2, varscan2
- DNAJC6 | c.144A>G p.T48= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as rs759323525, COSV99675619; called by muse, mutect2, varscan2
- DRC1 | c.1617T>C p.S539= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99985709; called by muse, mutect2, varscan2
- FAM83B | c.2052A>G p.V684= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100175003; called by muse, mutect2
- FOLH1 | c.1539C>T p.S513= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99923919; called by mutect2, varscan2
- FUBP3 | c.927G>A p.R309= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100156315; called by muse, mutect2, varscan2
- GLYAT | c.783C>A p.V261= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99557558; called by muse, mutect2, varscan2
- GRID1 | c.2220G>T p.L740= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100026443; called by muse, mutect2, varscan2
- HPS1 | c.1692G>A p.K564= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as COSV100282809; called by muse, mutect2, varscan2
- ICE1 | c.6582G>A p.S2194= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1409781025, COSV56830736, COSV99665685; called by muse, mutect2, varscan2
- KRTAP10-8 | c.513C>T p.C171= | Silent (SNP) | VAF 34/401 reads (8%) | catalogued as rs782462611, COSV58167202; called by muse, mutect2
- LTBP3 | c.2076G>A p.R692= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV57238905; called by muse, mutect2
- LVRN | c.678C>A p.T226= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs778369338, COSV100773258; called by muse, mutect2
- LVRN | c.1668A>T p.T556= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100773680; called by muse, mutect2, varscan2
- MC3R | c.582C>T p.T194= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV99710853; called by muse, mutect2, varscan2
- NAV2 | c.5718G>A p.Q1906= (on ENST00000396087 / NM_001244963.2; = p.Q1847= on NM_145117.5) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100217632, COSV60658775; called by muse, mutect2, varscan2
- NETO1 | c.1467C>T p.A489= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100199726; called by muse, mutect2, varscan2
- NKX6-1 | c.792C>A p.P264= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV99880194; called by muse, mutect2
- NRP2 | c.2577G>C p.L859= (on ENST00000360409 / NM_201266.2; = p.L854= on NM_003872.3) | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV63379097; called by muse, mutect2, varscan2
- OR2T4 | c.660C>A p.S220= | Silent (SNP) | VAF 24/213 reads (11%) | catalogued as COSV100822617; called by muse, mutect2, varscan2
- OR4A16 | c.93C>A p.L31= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV100125398, COSV59043257; called by muse, mutect2
- OR4K2 | c.297C>A p.T99= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as COSV53849469; called by muse, varscan2
- OR5K3 | c.343C>T p.L115= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as COSV101051692; called by muse, mutect2
- P4HB | c.942C>T p.A314= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs199705471, COSV100515925; called by muse, mutect2, varscan2
- PAPPA | c.696C>A p.T232= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100075269; called by muse, mutect2, varscan2
- PCDH15 | c.4302G>A p.A1434= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs368622542; called by muse, varscan2
- PCDHB8 | c.1812G>T p.S604= | Silent (SNP) | VAF 36/258 reads (14%) | catalogued as COSV50762944, COSV99177362; called by muse, mutect2, varscan2
- PHEX | c.555C>T p.F185= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as COSV101040013; called by muse, mutect2, varscan2
- PITPNM1 | c.1251G>A p.G417= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100711734; called by muse, mutect2, varscan2
- PLCB1 | c.3075T>C p.Y1025= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100572095; called by muse, mutect2, varscan2
- POLI | c.1782A>G p.V594= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99471257; called by muse, varscan2
- RAB25 | c.543A>G p.R181= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs776240771, COSV100737397; called by muse, mutect2, varscan2
- RFX6 | c.537A>G p.T179= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100264278; called by muse, mutect2, varscan2
- SAMD3 | c.498G>T p.P166= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100148415; called by muse, varscan2
- SETX | c.1068A>T p.V356= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99810888; called by muse, mutect2, varscan2
- SHANK1 | c.969G>A p.Q323= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99522019; called by muse, mutect2
- SLFN5 | c.2322G>T p.A774= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100249819, COSV55482524; called by muse, mutect2
- SPTA1 | c.2664T>A p.A888= | Silent (SNP) | VAF 19/237 reads (8%) | catalogued as COSV100935557; called by muse, mutect2
- SRSF6 | c.351T>A p.L117= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV99719838; called by muse, mutect2, varscan2
- SYNE3 | c.2298A>G p.K766= | Silent (SNP) | VAF 49/354 reads (14%) | catalogued as COSV100516477; called by muse, mutect2, varscan2
- TAF1L | c.2856C>T p.N952= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV99645394; called by muse, mutect2, varscan2
- TAF2 | c.486G>T p.V162= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as COSV100978800; called by muse, mutect2, varscan2
- TBC1D22B | c.1476C>A p.L492= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100996929; called by muse, mutect2, varscan2
- TCF21 | c.135G>A p.E45= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52819105; called by muse, mutect2, varscan2
- TDRD1 | c.2877A>G p.P959= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs144170696; called by muse, mutect2, varscan2
- TECTA | c.1854G>A p.T618= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs746142039, COSV99879463; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2047C>T p.L683= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99305531; called by muse, mutect2, varscan2
- TMPRSS15 | c.705T>A p.S235= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV99519263; called by muse, mutect2
- TRHDE | c.1495C>T p.L499= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99672444, COSV99673046; called by muse, mutect2, varscan2
- TTN | c.22116C>T p.D7372= (on ENST00000591111; = p.D6445= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs191854953, COSV60027381; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12486T>A p.A4162= (on ENST00000591111; = p.A4116= on NM_003319.4) | Silent (SNP) | VAF 19/221 reads (9%) | catalogued as COSV100629400; called by muse, mutect2
- TTN | c.5184C>A p.P1728= (on ENST00000591111; = p.P1682= on NM_003319.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100629402; called by muse, mutect2, varscan2
- USF3 | c.5122A>C p.R1708= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100325793; called by muse, mutect2, varscan2
- USH1C | c.901C>A p.R301= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs574790229, COSV99141976; called by muse, mutect2, varscan2
- USH2A | c.10302C>A p.S3434= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100242479; called by muse, mutect2, varscan2
- WDFY3 | c.2391C>A p.L797= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as COSV99885632; called by muse, mutect2, varscan2
- ZFHX4 | c.8781G>C p.P2927= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99267442; called by muse, mutect2
- ZNF407 | c.2358A>G p.K786= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs1568134220, COSV99996733; called by muse, mutect2, varscan2
- ZNF462 | c.867G>T p.P289= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV52952573, COSV99473259; called by muse, mutect2, varscan2
- ZNF516 | c.3039G>T p.L1013= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV101487368; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83212G>A | Intron (SNP) | VAF 76/395 reads (19%) | catalogued as rs751294206; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851963 C>A | 3'Flank (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501517 G>A | 5'Flank (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.718-992G>A | Intron (SNP) | VAF 66/265 reads (25%) | catalogued as rs1179061113, COSV62262842; called by muse, mutect2, varscan2
- CTSC | c.318+8498del | Intron (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- DCHS2 | n.7846G>T | RNA (SNP) | VAF 15/94 reads (16%) | catalogued as rs770448499, COSV100602627; called by muse, mutect2, varscan2
- FOLH1B | n.1968A>G | RNA (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1750T>G | RNA (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- NACA | c.70+4756C>G | Intron (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100771646; called by muse, mutect2, varscan2
- SMIM8 | c.*2A>G | 3'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99994825; called by muse, mutect2, varscan2
- SSPOP | n.5731C>T | RNA (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100022992; called by muse, mutect2, varscan2
